Surgical pathology report (de-identified scan), TCGA case TCGA-YF-AA3M, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Puerto Rico, specimen TCGA-YF-AA3M-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Spec #:

Taken:

Received:

Reported:

SPECIMEN

- A. Ureter
- B. Ureter
- C. BLADDER
- D. Appendix

*ICD O-3
Carcinoma, urothelial NOS 8120/3
Site: ^{Cyst} Bladder, lateral wall C67.2
^{path} Bladder NOS C67.9
JFD 5/20/14*

CLINICAL INFORMATION

Clinical History: Invasive CA Bladder

Pre-Operative Clinical Diagnosis: Bladder CA

Post-Operative Clinical Diagnosis: Bladder CA

INTRAOPERATIVE CONSULTATION DX

- A. Ureter, left, surgical margin biopsy:
- Negative for malignancy

- B. Ureter, right, surgical margin biopsy:
- Negative for malignancy

Pathologist:

FINAL PATHOLOGIC DIAGNOSIS

- A. Ureter, left, surgical margin biopsy:
- Negative for malignancy

- B. Ureter, right, surgical margin biopsy:
- Negative for malignancy

- C. Bladder and prostate, radical cystoprostatectomy:

1. Infiltrating urothelial carcinoma, high grade

- Tumor is 2 cm in main dimension
- Tumor invades lamina propria and inner half of muscularis propria
- Surgical margins are negative for malignancy
- Negative for perineural and lymphovascular invasion

pT2aNx

2. Adenocarcinoma of prostate, Gleason score 6 (3+3), involving both lobes (approximately 10% of the entire prostate gland)

- Margins of resection are free of tumor
- Negative for lymphovascular and perineural invasion

pT2cNx Stage IIB

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

- D. Vermiform appendix, appendectomy:
- Vermiform appendix

NOTE: Immunostains performed at
please see scanned report.

support the above diagnosis.

GROSS DESCRIPTION

A. Received fresh, labeled _____, is a pink tan segment of ureter that measures 0.6 cm in length by 0.5 cm in diameter. The entire specimen is frozen for intraoperative consultation in one tissue block. (ST1)

B. Received fresh, labeled _____, is a pink tan segment of ureter (0.6 x 0.5 cm). The entire specimen is frozen for intraoperative consultation in one tissue block. (ST1)

C. Received in formalin, labeled _____ is a radical cystoprostatectomy specimen containing bladder (8 x 6 x 4.5 cm), prostate (4 x 4 x 3 cm). There is a soft, tan-pink papillary tumor (2 x 1.5 x 1 cm) located at the posterior wall. The remainder of the bladder mucosa is edematous and congested; however, no other gross lesions are noted. The right and left ureters margins were submitted separately. The prostate consists of diffusely firm white parenchyma with a whorled appearance. The right seminal vesicle (2 x 1.5 x 1 cm), left seminal vesicle (2 x 1.3 x 1 cm), right vas deferens (2 cm in length by 0.4 cm in diameter), and left vas deferens (2 cm in length by 0.4 cm in diameter) are unremarkable. (RS15) 1: ureter margin, 2: right lateral, 3: left lateral, 4: anterior, 5: posterior tumor and defect, 6: tumor, 7: right seminal vesicle, 8: left seminal vesicle, 9: right lobe, 10: left lobe, 11: normal mucosa with tumor, _____ prostate

D. Received in formalin, labeled _____ is a vermiform appendix measuring 8.2 cm in length by 0.8 cm in diameter. The serosal surface is smooth and glistening. On section, the wall is tan and measures 0.1 cm in thickness. The mucosa is tan and appears intact. (RS1)

Dictated by: _____

CANCER REGISTRY

Copy to _____

REFERRED TESTS

See scanned report.

Source: NCI Genomic Data Commons file 02ffc7a8-bd77-46da-864b-dab575a5bd84 (TCGA-YF-AA3M.D0F09A8C-8431-4A41-B7A6-BE6E9621CC58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).